Gene-level copy-number profile of tumor specimen ALCH-B2FJ-TTP1-A from ALCHEMIST case ALCH-B2FJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.7 years (27,272 days).
Specimen ALCH-B2FJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 99eb8be0-e4f2-4a75-8065-d0d6b6e04e7b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2FJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/febe05f8-73bb-445f-bb73-b454c0cd3be1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 450; copy number 2: 30,913; copy number 3: 12,768; copy number 4: 13,818; copy number 5: 352; copy number 6: 4; copy number 7: 85; copy number 15: 1; copy number 23: 2; copy number 37: 2.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,523,648–49,524,185, 2 genes: AC119751.2, AC119751.8.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr10:95,173,085–95,173,187, 1 gene: AL157834.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 446 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:42,169,353–42,332,548, 1 gene, copy number 5 (within-gene range 4–5): EML4.
- chr5:58,198–1,634,005, 60 genes, copy number 5: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2.
- chr5:131,423,921–131,797,929, 6 genes, copy number 5 (within-gene range 4–5): RAPGEF6, AC008695.1, AC008497.1, FNIP1, ACTBP4, AC005593.1.
- chr7:37,032–2,664,802, 71 genes, copy number 5 (broad region; genes not listed).
- chr11:118,344,344–118,401,895, 3 genes, copy number 5 (within-gene range 3–5): CD3G, UBE4A, AP001267.1.
- chr14:22,197,446–22,482,959, 1 gene, copy number 7 (within-gene range 4–8): AC244502.1.
- chr14:22,415,362–22,552,156, 71 genes, copy number 7 (within-gene range 7–8) (broad region; genes not listed).
- chr14:99,397,748–99,480,889, 2 genes, copy number 7: SETD3, RNU6-91P.
- chr16:11,555–2,009,821, 181 genes, copy number 5 (broad region; genes not listed).
- chr16:87,949,244–88,715,396, 23 genes, copy number 5 (within-gene range 4–5): BANP, AC134312.4, AC134312.3, AC134312.1, AC134312.2, AC134312.5, LINC02182, AC134312.6, AC138512.1, ZNF469, ZFPM1, MIR5189, AC116552.1, ZC3H18, IL17C, CYBA, MVD, SNAI3-AS1, SNAI3, RNF166, AC138028.3, CTU2, AC138028.6.
- chr19:1,228,287–1,259,140, 4 genes, copy number 6–15 (within-gene range 2–15): CBARP, AC004221.1, ATP5F1D, MIDN.
- chr19:2,249,309–2,269,759, 3 genes, copy number 7 (within-gene range 2–7): AMH, MIR4321, JSRP1.
- chr22:18,400,407–18,577,968, 9 genes, copy number 6–7: PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1.
- chr22:18,615,581–18,653,617, 4 genes, copy number 23–37: Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.
- chr22:18,773,665–18,843,399, 2 genes, copy number 5 (within-gene range 4–5): GGT3P, AC008132.2.
- chr22:18,873,543–18,947,732, 5 genes, copy number 5 (within-gene range 4–5): FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 447. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
